Somatic mutation profile of tumor specimen MMRF_1672_1_BM_CD138pos (aliquot MMRF_1672_1_BM_CD138pos_T1_KBS5U_K11339) from MMRF case MMRF_1672, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.8 years (21,116 days).
Specimen MMRF_1672_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26dbf086-961a-4b39-ac71-208bf5e7245c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1672_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1672_1_PB_Whole_C2_KBS5U_K11340; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae1b1b3c-036a-4709-9a65-efbb21a33948

The open-access MAF lists 144 somatic variants for this specimen: 50 protein-altering or splice-affecting, 9 silent, 85 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 50, Missense Mutation 41, Intron 23, Silent 9, Frame Shift Del 5, 5'UTR 4, 3'Flank 4, 5'Flank 3, Nonsense Mutation 2, Splice Region 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2A | c.1431G>T p.E477D (on ENST00000219054; = p.E398D on NM_001308169.2) | Missense Mutation (SNP) | VAF 90/187 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs759108235; called by muse, mutect2, varscan2
- AMBRA1 | c.3016C>T p.R1006W (on ENST00000458649 / NM_001367468.1; = p.R916W on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 148/226 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs750314722, COSV54053056; called by muse, mutect2, varscan2
- BSN | c.10994G>A p.R3665H | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs945799503; called by muse, mutect2, varscan2
- GATA4 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1435631810; called by muse, mutect2, varscan2
- GLP2R | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs748318508; called by muse, mutect2, varscan2
- IGLL5 | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1331308322, COSV101597142; called by muse, mutect2, varscan2
- KCTD12 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs773460579; called by muse, mutect2, varscan2
- RIMS2 | c.3254G>A p.R1085H (on ENST00000666250 / NM_001348490.2; = p.R893H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.125); catalogued as rs377554442; called by muse, mutect2, varscan2
- TRPV6 | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63891583; called by muse, mutect2
- VPS39 | c.60T>G p.C20W | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV58788487; called by muse, mutect2, varscan2
- YPEL4 | c.294T>C p.Y98= | Splice Region (SNP) | VAF 20/99 reads (20%) | catalogued as rs777383865; called by muse, mutect2, varscan2
- ZNFX1 | c.1405G>A p.V469I | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs774879663; called by muse, mutect2, varscan2
- ALDH9A1 | c.162A>T p.K54N | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARID1A | c.3058_3059del p.R1020Efs*12 | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | called by pindel, varscan2
- ARNT2 | c.2117T>C p.F706S | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ASXL1 | c.4055C>T p.P1352L | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATP1B4 | c.724A>G p.T242A (on ENST00000218008 / NM_001142447.3; = p.T238A on NM_012069.5) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- BAZ1A | c.3206C>G p.T1069R | Missense Mutation (SNP) | VAF 69/102 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHGB | c.655A>G p.T219A | Missense Mutation (SNP) | VAF 58/95 reads (61%) | SIFT tolerated (0.83); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPHA8 | c.1624A>G p.T542A | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FAR1 | c.1350G>A p.M450I | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- HTR1E | c.8T>C p.I3T | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFIH1 | c.165C>G p.N55K | Missense Mutation (SNP) | VAF 72/220 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- KIRREL1 | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 9/290 reads (3%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- LRBA | c.2234A>C p.Y745S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYF6 | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 71/129 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYOCD | c.2249T>C p.M750T | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- NAV3 | c.6884A>G p.D2295G (on ENST00000397909 / NM_001024383.2; = p.D2273G on NM_014903.6) | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- NOX1 | c.1688A>T p.N563I | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- NRG3 | c.697T>C p.S233P | Missense Mutation (SNP) | VAF 106/235 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OR7G2 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 37/133 reads (28%) | called by muse, mutect2, varscan2
- PCCA | c.1238C>A p.S413Y | Missense Mutation (SNP) | VAF 90/190 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB44 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RBBP7 | c.1160G>T p.W387L | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- RNF128 | c.324G>T p.W108C | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2
- SAFB2 | c.1930C>G p.Q644E | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SCAF4 | c.1095G>T p.M365I | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEC24B | c.1676C>A p.S559* | Nonsense Mutation (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- SHROOM3 | c.3747del p.K1249Nfs*16 | Frame Shift Del (DEL) | VAF 64/184 reads (35%) | called by mutect2, pindel, varscan2
- SIGLEC8 | c.773A>T p.D258V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SIPA1L2 | c.608T>C p.L203S | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- SMARCA2 | c.1373del p.H458Lfs*49 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | called by mutect2, pindel, varscan2
- SVEP1 | c.7511T>A p.I2504N | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- TMEM161A | c.284del p.L95Rfs*50 | Frame Shift Del (DEL) | VAF 34/141 reads (24%) | called by mutect2, pindel, varscan2
- TRAF3 | c.136del p.T46Pfs*36 | Frame Shift Del (DEL) | VAF 25/33 reads (76%) | called by mutect2, pindel, varscan2
- TRIOBP | c.4217A>T p.E1406V | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- UNC13C | c.3989-2A>G p.X1330_splice | Splice Site (SNP) | VAF 32/52 reads (62%) | called by muse, mutect2, varscan2
- ZFHX4 | c.10364C>T p.A3455V | Missense Mutation (SNP) | VAF 79/220 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ZFP36L2 | c.525G>T p.Q175H | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- ZKSCAN4 | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 88/165 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ACAP1 | c.60T>A p.S20= | Silent (SNP) | VAF 68/137 reads (50%) | called by muse, mutect2, varscan2
- AKNA | c.24C>A p.I8= | Silent (SNP) | VAF 123/164 reads (75%) | catalogued as COSV56313130; called by muse, mutect2, varscan2
- DSCAML1 | c.4821C>T p.Y1607= (on ENST00000321322; = p.Y1547= on NM_020693.4) | Silent (SNP) | VAF 54/169 reads (32%) | catalogued as rs769549585, COSV58391951; called by muse, mutect2, varscan2
- DUSP15 | c.855T>C p.P285= | Silent (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2, varscan2
- EEF1B2 | c.177C>A p.I59= | Silent (SNP) | VAF 24/304 reads (8%) | catalogued as COSV51908474; called by muse, mutect2
- GARRE1 | c.2004G>A p.V668= | Silent (SNP) | VAF 43/195 reads (22%) | called by muse, mutect2, varscan2
- PPARGC1B | c.1056C>G p.L352= | Silent (SNP) | VAF 64/234 reads (27%) | called by muse, mutect2, varscan2
- PPP6R3 | c.642A>T p.S214= | Silent (SNP) | VAF 46/234 reads (20%) | called by muse, mutect2, varscan2
- SCAF4 | c.939T>C p.P313= | Silent (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- ABCB9 | c.*34G>T | 3'UTR (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2
- ADAMTS3 | c.*1036A>T | 3'UTR (SNP) | VAF 45/115 reads (39%) | called by muse, mutect2, varscan2
- AHSG | c.*373A>T | 3'UTR (SNP) | VAF 10/40 reads (25%) | called by muse, varscan2
- AL031777.2 | c.-27G>A | 5'UTR (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850939 A>G | 3'Flank (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- ANGPT2 | c.*2835T>C | 3'UTR (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2
- ATP5PO | c.441+481C>T | Intron (SNP) | VAF 25/49 reads (51%) | catalogued as rs994994341; called by muse, mutect2, varscan2
- ATP6V0B | c.591+328G>C | Intron (SNP) | VAF 75/152 reads (49%) | called by muse, mutect2, varscan2
- ATRX | c.5566+228C>G | Intron (SNP) | VAF 16/26 reads (62%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021378 A>G | 5'Flank (SNP) | VAF 42/87 reads (48%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021462 G>C | 5'Flank (SNP) | VAF 34/89 reads (38%) | catalogued as COSV55847618, COSV55848399; called by muse, mutect2, varscan2
- BIRC6 | c.*875G>T | 3'UTR (SNP) | VAF 32/49 reads (65%) | called by muse, mutect2, varscan2
- C12orf77 | n.431C>G | RNA (SNP) | VAF 99/168 reads (59%) | called by muse, mutect2, varscan2
- CCDC82 | c.*654A>G | 3'UTR (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- CDH19 | c.*1587T>C | 3'UTR (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- CDH19 | c.*309T>C | 3'UTR (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- CMKLR1 | c.*3754C>A | 3'UTR (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- CNOT3 | c.484-24G>C | Intron (SNP) | VAF 23/149 reads (15%) | called by muse, mutect2, varscan2
- CNOT6L | c.*2290G>A | 3'UTR (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- COL5A2 | c.*1322T>C | 3'UTR (SNP) | VAF 44/184 reads (24%) | called by muse, mutect2, varscan2
- CREB5 | c.*533T>C | 3'UTR (SNP) | VAF 48/174 reads (28%) | called by muse, mutect2
- CUEDC1 | c.1094-76C>T | Intron (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- CYP4B1 | c.*285C>T | 3'UTR (SNP) | VAF 9/46 reads (20%) | catalogued as rs1233479541; called by muse, mutect2, varscan2
- DCLK3 | c.-335G>A | 5'UTR (SNP) | VAF 24/86 reads (28%) | catalogued as rs1378902984; called by muse, mutect2, varscan2
- DDX39B | c.-3+564C>G | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- DUT | c.703-71G>A | Intron (SNP) | VAF 39/184 reads (21%) | called by muse, mutect2, varscan2
- ELAVL2 | chr9:23690492 G>T | 3'Flank (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- FAM98B | c.531+104A>G | Intron (SNP) | VAF 16/22 reads (73%) | catalogued as rs1366495131; called by muse, mutect2
- GBGT1 | c.360-118A>G | Intron (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2
- GNG4 | c.*1209C>T | 3'UTR (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- GPR85 | c.*1070A>T | 3'UTR (SNP) | VAF 26/102 reads (25%) | called by muse, mutect2, varscan2
- HTT | c.*1528C>T | 3'UTR (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
- IFIH1 | c.622+152T>G | Intron (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- KLF7 | c.*1246G>A | 3'UTR (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2, varscan2
- LGI3 | c.*1017G>A | 3'UTR (SNP) | VAF 54/114 reads (47%) | catalogued as rs1452940576; called by muse, mutect2, varscan2
- LMCD1 | c.*142G>A | 3'UTR (SNP) | VAF 17/58 reads (29%) | catalogued as rs1186145668; called by muse, mutect2, varscan2
- LRRC3 | c.*1326A>T | 3'UTR (SNP) | VAF 10/147 reads (7%) | called by muse, mutect2
- LYPD6B | c.157+712G>T | Intron (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- LYRM9 | c.219+64C>A | Intron (SNP) | VAF 30/93 reads (32%) | catalogued as rs1200374368; called by muse, mutect2, varscan2
- MACROH2A1 | c.-33-135C>T | Intron (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- MAPK8 | c.*2669A>C | 3'UTR (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- MIRLET7A3 | chr22:46110982 G>A | 5'Flank (SNP) | VAF 71/202 reads (35%) | catalogued as rs931093428; called by muse, mutect2, varscan2
- MMD2 | c.*1156G>T | 3'UTR (SNP) | VAF 38/172 reads (22%) | called by muse, mutect2, varscan2
- MS4A1 | c.*1903dup | 3'UTR (INS) | VAF 24/130 reads (18%) | catalogued as rs984081389; called by mutect2, varscan2
- MTURN | c.*4961T>A | 3'UTR (SNP) | VAF 33/52 reads (63%) | catalogued as rs1376343604; called by muse, varscan2
- NEK7 | c.*663T>C | 3'UTR (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- NINJ2 | c.33+19920A>G | Intron (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- NOD1 | c.*413C>T | 3'UTR (SNP) | VAF 28/89 reads (31%) | called by muse, mutect2, varscan2
- NPAP1 | c.*2347C>A | 3'UTR (SNP) | VAF 12/71 reads (17%) | catalogued as COSV100274935; called by muse, mutect2, varscan2
- NUMA1 | c.4650+78G>T | Intron (SNP) | VAF 6/19 reads (32%) | catalogued as COSV61192319; called by muse, mutect2, varscan2
- OBSCN | c.18662-2793G>A | Intron (SNP) | VAF 19/32 reads (59%) | called by muse, mutect2, varscan2
- OR10H2 | c.*22A>T | 3'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- PGK1 | c.*2796G>T | 3'UTR (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- PHEX | c.*2730C>A | 3'UTR (SNP) | VAF 45/69 reads (65%) | called by muse, mutect2, varscan2
- PLEKHG2 | c.*303G>A | 3'UTR (SNP) | VAF 15/116 reads (13%) | catalogued as rs919273523; called by muse, mutect2, varscan2
- PPP1R16A | c.-447C>T | 5'UTR (SNP) | VAF 63/133 reads (47%) | called by muse, mutect2, varscan2
- PTGFR | c.*1391T>C | 3'UTR (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- RABIF | c.*554G>T | 3'UTR (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- RANBP17 | c.*441T>C | 3'UTR (SNP) | VAF 25/129 reads (19%) | catalogued as rs985014026; called by muse, mutect2, varscan2
- RPS17 | c.*1055A>G | 3'UTR (SNP) | VAF 252/720 reads (35%) | catalogued as rs1327725931; called by muse, mutect2, varscan2
- SGCE | chr7:94585241 T>A | 3'Flank (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- SLC12A1 | c.725-286C>T | Intron (SNP) | VAF 15/47 reads (32%) | catalogued as rs781729662; called by muse, mutect2, varscan2
- SLC25A26 | c.-42T>A | 5'UTR (SNP) | VAF 60/190 reads (32%) | called by muse, mutect2, varscan2
- SLC39A13 | c.735+111T>C | Intron (SNP) | VAF 122/398 reads (31%) | called by muse, mutect2, varscan2
- SNX19 | c.*888T>G | 3'UTR (SNP) | VAF 6/68 reads (9%) | catalogued as rs1022518642; called by muse, mutect2
- TAF1L | c.*123T>C | 3'UTR (SNP) | VAF 31/184 reads (17%) | called by muse, mutect2, varscan2
- TMEM170B | c.*134G>C | 3'UTR (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- TRAF6 | chr11:36488503 A>T | 3'Flank (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- TRIM68 | c.*1435G>T | 3'UTR (SNP) | VAF 12/64 reads (19%) | called by muse, varscan2
- TTN | c.41506+34A>G | Intron (SNP) | VAF 67/194 reads (35%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*1220G>A | 3'UTR (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*901C>T | 3'UTR (SNP) | VAF 43/74 reads (58%) | called by muse, mutect2, varscan2
- UBE2D2 | c.*189C>A | 3'UTR (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- UCMA | c.*83C>T | 3'UTR (SNP) | VAF 43/103 reads (42%) | catalogued as rs900080269; called by muse, mutect2, varscan2
- UGT2A3 | c.*689_*732delinsTCTCACATAGAGAACATGTCAGTAAGATATTCAAGGTGAACAGA | 3'UTR (ONP) | VAF 15/98 reads (15%) | called by mutect2*, pindel, varscan2*
- UTP6 | c.*1361A>G | 3'UTR (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- VSTM2A | c.*1470A>C | 3'UTR (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- WDR1 | c.138+49dup | Intron (INS) | VAF 5/35 reads (14%) | called by mutect2, pindel
- WDR43 | c.*1037A>G | 3'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as rs916095901; called by muse, mutect2
- ZC3H12B | c.*4007A>T | 3'UTR (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- ZFYVE19 | c.280-56G>A | Intron (SNP) | VAF 76/198 reads (38%) | called by muse, mutect2, varscan2
- ZMYND15 | c.1683+74C>T | Intron (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2
- ZNF254 | c.157+26C>T | Intron (SNP) | VAF 75/320 reads (23%) | catalogued as rs963381141; called by muse, mutect2, varscan2
- ZNF385D | c.*1232A>G | 3'UTR (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- ZNF512 | c.*906G>A | 3'UTR (SNP) | VAF 22/209 reads (11%) | catalogued as rs549966042; called by muse, mutect2, varscan2
